Gene-level copy-number profile of tumor specimen ALCH-B4EC-TTP1-A from ALCHEMIST case ALCH-B4EC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 45.3 years (16,564 days).
Specimen ALCH-B4EC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86909866-51d9-4985-b2b3-cf636cab735f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4EC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/8af58971-dbc7-4d9b-8a52-3acf9f4f0dd2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 7,298; copy number 2: 48,181; copy number 3: 2,887; copy number 4: 8; copy number 6: 2; copy number 7: 1; copy number 8: 2; copy number 10: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,936,131–156,936,244, 1 gene (within-gene range 0–2): MIR765.
- chr1:165,497,724–165,498,348, 1 gene (within-gene range 0–2): PRELID1P7.
- chr1:202,133,404–202,161,588, 2 genes (within-gene range 0–2): ARL8A, PTPN7.
- chr3:52,777,595–52,809,009, 2 genes: ITIH1, ITIH3.
- chr3:196,988,621–197,029,817, 2 genes: MELTF, MELTF-AS1.
- chr6:31,945,650–31,959,038, 3 genes (within-gene range 0–2): CFB, NELFE, MIR1236.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:93,121,496–93,134,251, 1 gene: NINJ1.
- chr11:71,787,510–71,801,237, 1 gene (within-gene range 0–2): FAM86C1P.
- chr11:71,865,509–71,928,654, 4 genes (within-gene range 0–2): AP002495.1, DEFB131B, OR7E128P, OR7E126P.
- chr12:132,550,729–132,554,947, 1 gene (within-gene range 0–2): AC131212.3.
- chr15:70,503,907–70,505,928, 1 gene: LINC02205.
- chr16:4,658,851–4,659,151, 1 gene (within-gene range 0–1): Metazoa_SRP.
- chr17:50,171,428–50,181,178, 1 gene (within-gene range 0–2): H1-9P.
- chr17:57,448,218–57,450,291, 1 gene (within-gene range 0–2): AC015883.1.
- chr20:57,214,872–57,215,866, 1 gene (within-gene range 0–2): BMP7-AS1.
- chr21:9,082,601–9,088,391, 2 genes (within-gene range 0–1): SOWAHCP2, CR392039.2.
- chr22:23,261,782–23,265,005, 2 genes (within-gene range 0–2): RN7SL263P, FBXW4P1.
- chr22:25,756,318–25,756,669, 1 gene (within-gene range 0–1): AL022329.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,583,731–105,588,395, 1 gene, copy number 7: IGHA2.
- chr16:28,379,579–28,403,841, 2 genes, copy number 8: EIF3CL, MIR6862-1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 17: PWP2.
- chr21:44,172,169–44,194,338, 2 genes, copy number 10: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 6,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
